Somatic mutation profile of tumor specimen TCGA-QK-A6IF-01A (aliquot TCGA-QK-A6IF-01A-11D-A31L-08) from TCGA case TCGA-QK-A6IF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: GX; Age at diagnosis: 61.5 years (22,463 days).
Specimen TCGA-QK-A6IF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e9eea77-e939-48fb-be33-57c5bdff492c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QK-A6IF-10A (Blood Derived Normal), aliquot TCGA-QK-A6IF-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4923703b-ecf9-42c3-b709-9a3d21844e66

The open-access MAF lists 28 somatic variants for this specimen: 20 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 19, Silent 8, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as COSV100856809, COSV63977634; called by muse, mutect2, varscan2
- ADCY2 | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as rs866989574, COSV57857225, COSV57893995; called by muse, mutect2
- ANKS6 | c.1007C>T p.T336M | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as rs376870807, COSV62052431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF1A1 | c.1016G>A p.G339D | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.201); catalogued as COSV100303316; called by muse, mutect2, varscan2
- FBXW12 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99601631; called by muse, mutect2, varscan2
- HLA-A | c.449T>A p.L150Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs281864753, COSV100954429, COSV65138189; called by muse, mutect2, varscan2
- HMCN1 | c.15340G>A p.G5114R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV99629411; called by muse, mutect2, varscan2
- INO80 | c.1013G>A p.R338H | Missense Mutation (SNP) | VAF 55/196 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs749332663, COSV62737727; called by muse, mutect2, varscan2
- MUC17 | c.3686C>T p.T1229M | Missense Mutation (SNP) | VAF 113/418 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs771303338, COSV60281126; called by muse, mutect2, varscan2
- NECAB1 | c.1010C>A p.T337K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV101341091, COSV70243676; called by muse, mutect2, varscan2
- NPAS2 | c.1271C>T p.S424L | Missense Mutation (SNP) | VAF 27/33 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100176211; called by muse, mutect2, varscan2
- PDLIM1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV61474763; called by muse, mutect2, varscan2
- PTTG1IP | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs143122508, COSV58366065; called by muse, mutect2, varscan2
- RAB17 | c.600C>A p.N200K | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV99221307; called by muse, mutect2, varscan2
- SAMD11 | c.752G>A p.G251D | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs763202330, COSV100498021; called by mutect2, varscan2
- SEC24B | c.3146C>T p.S1049L | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.39); PolyPhen benign (0.046); catalogued as rs199826133, COSV99493536; called by muse, mutect2, varscan2
- SPDL1 | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.067); catalogued as COSV99517548; called by muse, mutect2, varscan2
- ZFC3H1 | c.2636A>T p.E879V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101110538; called by muse, mutect2, varscan2
- ZNF799 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.622); catalogued as rs1489723242, COSV101345263, COSV70122436; called by muse, mutect2, varscan2
- IRS4 | c.449dup p.Y151Ifs*82 | Frame Shift Ins (INS) | VAF 22/50 reads (44%) | called by mutect2, pindel, varscan2
- ABO | c.879C>T p.N293= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as rs781867861, COSV101505959; called by muse, mutect2, varscan2
- ASCL1 | c.363G>A p.A121= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs778284097, COSV57150918; called by muse, mutect2, varscan2
- CDK15 | c.462G>A p.K154= (on ENST00000652192 / NM_001366386.2; = p.K103= on NM_139158.2) | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as rs776071767, COSV99643159; called by muse, mutect2, varscan2
- FLG | c.4623C>T p.S1541= | Silent (SNP) | VAF 44/426 reads (10%) | catalogued as COSV100911586; called by muse, mutect2
- KPNA6 | c.435T>G p.A145= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as COSV101012509; called by muse, mutect2, varscan2
- ORAI3 | c.222C>T p.F74= | Silent (SNP) | VAF 7/18 reads (39%) | catalogued as rs1379532464, COSV57944825; called by muse, mutect2, varscan2
- SRSF5 | c.231A>G p.R77= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV101275286; called by muse, mutect2
- TC2N | c.498C>T p.P166= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as rs760754765, COSV100562916; called by muse, mutect2
